Gene-level copy-number profile of tumor specimen TCGA-57-1586-01A from TCGA case TCGA-57-1586, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.5 years (24,304 days).
Specimen TCGA-57-1586-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8071cdd3-94c7-4863-945d-0977eab87107.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1586-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 409 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90e4ab16-f325-4166-8aad-6c1ad8950ed1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 2,640; copy number 2: 34,054; copy number 3: 13,910; copy number 4: 6,390; copy number 5: 1,564; copy number 6: 405; copy number 9: 250; copy number 11: 96; copy number 13: 338; copy number 15: 8; copy number 17: 19; copy number 21: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-57-1586-01A-02D-0559-01): tumor purity 0.84, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr19:42,752,686–42,950,387, 8 genes (within-gene range 0–2): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7.
- chr19:43,007,656–43,041,248, 2 genes: PSG11, CEACAMP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,685 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,850,694–43,991,170, 292 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:63,523,372–63,572,693, 1 gene, copy number 9 (within-gene range 4–9): EFCAB7.
- chr1:63,547,082–64,833,232, 21 genes, copy number 9: DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2.
- chr1:64,918,443–64,918,683, 1 gene, copy number 9: AL606517.2.
- chr1:117,025,482–118,264,489, 23 genes, copy number 5 (within-gene range 2–5): AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56.
- chr1:143,541,768–152,047,907, 343 genes, copy number 13–21 (broad region; genes not listed).
- chr1:202,193,901–202,319,781, 1 gene, copy number 6 (within-gene range 4–6): LGR6.
- chr3:93,843,764–100,325,251, 92 genes, copy number 5 (broad region; genes not listed).
- chr3:128,619,969–128,681,075, 3 genes, copy number 6: RPN1, Metazoa_SRP, POU5F1P6.
- chr3:139,389,761–139,782,699, 1 gene, copy number 5 (within-gene range 4–5): AC046134.2.
- chr3:139,493,809–198,222,513, 1,019 genes, copy number 5–6 (broad region; genes not listed).
- chr7:44,104,345–52,503,434, 129 genes, copy number 6–17 (broad region; genes not listed).
- chr7:56,477,588–62,275,678, 88 genes, copy number 5 (broad region; genes not listed).
- chr12:54,016,931–54,056,030, 1 gene, copy number 5 (within-gene range 3–5): HOXC4.
- chr12:54,032,853–54,634,895, 36 genes, copy number 5 (within-gene range 3–5): HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT.
- chr17:4,163,821–4,263,995, 1 gene, copy number 5 (within-gene range 3–5): ANKFY1.
- chr17:4,222,091–4,268,430, 2 genes, copy number 5: RYKP1, AC087742.1.
- chr17:32,227,890–32,997,877, 33 genes, copy number 5: UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:33,052,107–33,131,743, 3 genes, copy number 5 (within-gene range 3–5): AC003687.1, AC008133.2, AC008133.1.
- chr17:36,534,987–36,634,698, 6 genes, copy number 6: PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2.
- chr17:36,861,674–37,056,871, 9 genes, copy number 5: LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 5: AC244093.1, HMGB1P24, AC244093.2.
- chr17:47,117,703–50,562,108, 180 genes, copy number 5 (broad region; genes not listed).
- chr17:50,563,203–50,563,783, 1 gene, copy number 5: AC021491.3.
- chr17:60,122,642–63,548,977, 96 genes, copy number 11 (broad region; genes not listed).
- chr20:7,347,451–24,446,314, 284 genes, copy number 5–6 (broad region; genes not listed).
- chr20:24,491,472–24,502,345, 1 gene, copy number 5: AL157413.1.
- chr20:43,458,054–44,069,616, 15 genes, copy number 5 (within-gene range 4–5): AL031681.2, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P.

Autosomal genes at a single copy (total copy number 1): 1,755. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
